Somatic mutation profile of tumor specimen TCGA-06-0877-01A (aliquot TCGA-06-0877-01A-01W-0424-08) from TCGA case TCGA-06-0877, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 78.7 years (28,760 days).
Specimen TCGA-06-0877-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08090c9b-b719-4dfe-ba0e-b110adbdf61f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0877-10A (Blood Derived Normal), aliquot TCGA-06-0877-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8b1e3e0-25ce-4403-a7db-dff72f6a0edb

The open-access MAF lists 113 somatic variants for this specimen: 93 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Frame Shift Ins 23, Silent 19, Nonsense Mutation 5, Splice Region 2, Intron 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTG2 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 55/186 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.108); catalogued as rs869312168, COSV61828224; ClinVar: pathogenic; called by muse, mutect2, varscan2
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 41/214 reads (19%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CDCA7 | c.911G>A p.R304H (on ENST00000347703 / NM_145810.3; = p.R383H on NM_031942.5) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs772929976, CM157793, COSV60720077; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CPAMD8 | c.2352dup p.R785Qfs*23 (on ENST00000651564; = p.R738Qfs*23 on NM_015692.5) | Frame Shift Ins (INS) | VAF 22/180 reads (12%) | catalogued as rs756064750; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1126G>A p.G376R (on ENST00000521381 / NM_181523.3; = p.G106R on NM_181504.4) | Missense Mutation (SNP) | VAF 57/153 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519757, COSV57123316, COSV57132021, COSV57133701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAM23 | c.2340dup p.K781Qfs*3 | Frame Shift Ins (INS) | VAF 16/122 reads (13%) | catalogued as rs767549806; called by mutect2, varscan2
- ADAMTS16 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs752666810, COSV56987513, COSV57008464; called by muse, mutect2, varscan2
- ADCK1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 224/1547 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.749); catalogued as COSV53081928; called by muse, mutect2, varscan2
- ADCY5 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV71901346; called by muse, mutect2, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 102/435 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by muse, mutect2, varscan2
- AFM | c.1597G>A p.A533T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV56919978; called by muse, mutect2, varscan2
- ALDH5A1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62373425; called by muse, mutect2, varscan2
- AMD1 | c.224G>A p.R75K | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV64387347; called by muse, mutect2, varscan2
- ARFGEF1 | c.4655dup p.P1553Tfs*7 | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | catalogued as rs774148781; called by mutect2, varscan2
- ATP10B | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs371457894, COSV59150292; called by muse, mutect2, varscan2
- BAG6 | c.1169dup p.T391Nfs*29 | Frame Shift Ins (INS) | VAF 12/58 reads (21%) | catalogued as rs745882580; called by mutect2, varscan2
- C3 | c.4398C>A p.Y1466* | Nonsense Mutation (SNP) | VAF 116/494 reads (23%) | catalogued as COSV55568459; called by muse, mutect2, varscan2
- CA10 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 101/1497 reads (7%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.917); catalogued as COSV99563557; called by muse, mutect2
- CD22 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs571005886, COSV50052116; called by muse, mutect2, varscan2
- CD248 | c.1930dup p.Q644Pfs*41 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | catalogued as rs752025310; called by pindel, varscan2
- CHD7 | c.5783A>T p.Q1928L | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV71109814; called by muse, mutect2, varscan2
- CHST9 | c.1256G>A p.R419K | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.021); catalogued as rs1424937193; called by muse, mutect2
- CTBS | c.835dup p.A279Gfs*4 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs758636345; called by pindel, varscan2
- DGKG | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 110/313 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.034); catalogued as COSV53964618; called by muse, mutect2, varscan2
- DHTKD1 | c.1019G>T p.G340V | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976767270, COSV53802229; called by mutect2, varscan2
- DHX32 | c.1725C>G p.F575L | Missense Mutation (SNP) | VAF 46/510 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as COSV52941905; called by muse, mutect2
- ELF5 | c.227G>A p.C76Y (on ENST00000312319 / NM_198381.2; = p.C66Y on NM_001422.4) | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); catalogued as COSV56628783, COSV56630367; called by muse, mutect2, varscan2
- EPHA3 | c.2030T>A p.F677Y | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60703826; called by muse, mutect2, varscan2
- ERBB2 | c.3595C>A p.P1199T | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.145); catalogued as rs779469693, COSV54069598; called by muse, mutect2, varscan2
- FAM151A | c.351dup p.T118Hfs*5 | Frame Shift Ins (INS) | VAF 50/414 reads (12%) | catalogued as rs749953492; called by mutect2, varscan2
- FAM219A | c.492dup p.K165Qfs*39 (on ENST00000445726; = p.K148Qfs*39 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 14/92 reads (15%) | catalogued as rs760074479; called by mutect2, varscan2
- FRMD4A | c.3014dup p.S1006Kfs*25 | Frame Shift Ins (INS) | VAF 14/109 reads (13%) | catalogued as rs752538869; called by mutect2, varscan2
- GALNT1 | c.315G>A p.G105= | Splice Region (SNP) | VAF 175/550 reads (32%) | catalogued as COSV52452103; called by muse, mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 48/411 reads (12%) | catalogued as rs768450027; called by mutect2, varscan2
- GNAZ | c.612dup p.Q205Afs*35 | Frame Shift Ins (INS) | VAF 31/220 reads (14%) | catalogued as rs752075537; called by mutect2, varscan2
- GSTA4 | c.177A>C p.E59D | Missense Mutation (SNP) | VAF 969/2616 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV63955422; called by muse, mutect2, varscan2
- IRS1 | c.1951A>G p.R651G | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV59335961; called by muse, mutect2, varscan2
- KIF16B | c.1555G>T p.G519W | Missense Mutation (SNP) | VAF 88/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61705549; called by muse, mutect2, varscan2
- KIF2B | c.1129del p.E378Rfs*24 | Frame Shift Del (DEL) | VAF 22/76 reads (29%) | catalogued as COSV52131714; called by mutect2, pindel, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 72/334 reads (22%) | catalogued as rs757410385; called by mutect2, varscan2
- MAP3K12 | c.2234G>A p.R745H | Missense Mutation (SNP) | VAF 723/1309 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.211); catalogued as rs149876591; called by muse, mutect2, varscan2
- NUP214 | c.4133dup p.V1379Gfs*60 | Frame Shift Ins (INS) | VAF 31/230 reads (13%) | catalogued as rs780417788; called by mutect2, varscan2
- OPRPN | c.301G>T p.G101C | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.378); catalogued as COSV68192848; called by muse, mutect2, varscan2
- OR5D13 | c.715A>T p.T239S | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV62333531, COSV62334955; called by muse, mutect2, varscan2
- OR5L2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 238/661 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65723904, COSV65725055; called by muse, mutect2, varscan2
- OR5W2 | c.588G>C p.E196D | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs770746761, COSV60615861; called by muse, mutect2, varscan2
- OR9G1 | c.412A>T p.K138* | Nonsense Mutation (SNP) | VAF 87/400 reads (22%) | catalogued as COSV56452365; called by muse, mutect2, varscan2
- OR9G1 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 46/284 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.068); catalogued as COSV56450124; called by muse, mutect2, varscan2
- PARP6 | c.1813G>A p.D605N | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1567150212; called by muse, mutect2
- PCSK6 | c.745C>A p.R249S | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59342913; called by muse, mutect2, varscan2
- PHACTR1 | c.759dup p.P254Afs*78 | Frame Shift Ins (INS) | VAF 12/77 reads (16%) | catalogued as rs749326031; called by mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 70/522 reads (13%) | catalogued as rs749506841; called by mutect2, varscan2
- POLR3C | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 528/1433 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV61936414; called by muse, mutect2, varscan2
- PUM1 | c.441G>C p.L147F | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57084640; called by muse, mutect2, varscan2
- PWWP3A | c.1347G>A p.M449I (on ENST00000627377; = p.M448I on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/561 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs771561494; called by muse, mutect2, varscan2
- RHAG | c.1137A>C p.T379= | Splice Region (SNP) | VAF 5/42 reads (12%) | catalogued as COSV57705317; called by muse, mutect2
- RICTOR | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as COSV57121293; called by muse, mutect2, varscan2
- RIMS2 | c.3855G>C p.M1285I | Missense Mutation (SNP) | VAF 105/336 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.067); catalogued as COSV51701223; called by muse, mutect2, varscan2
- RPS5 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.068); catalogued as COSV52191370; called by muse, mutect2, varscan2
- RUVBL2 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1354933170, COSV55485016; called by muse, mutect2, varscan2
- SERPINA1 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as rs140814100, CM900181; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- SETD7 | c.1026dup p.G343Rfs*6 | Frame Shift Ins (INS) | VAF 18/121 reads (15%) | catalogued as rs35259575; called by mutect2, varscan2
- SLC24A2 | c.119T>G p.L40* | Nonsense Mutation (SNP) | VAF 20/24 reads (83%) | catalogued as COSV53863777; called by muse, mutect2, varscan2
- SLC9A2 | c.2243dup p.T749Nfs*22 | Frame Shift Ins (INS) | VAF 9/60 reads (15%) | catalogued as rs748701652; called by mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 8/74 reads (11%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SSH2 | c.2756dup p.E920Rfs*22 | Frame Shift Ins (INS) | VAF 10/68 reads (15%) | catalogued as rs752567808; called by mutect2, varscan2
- TBC1D4 | c.1170+1G>A p.X390_splice | Splice Site (SNP) | VAF 95/321 reads (30%) | catalogued as COSV66490357; called by muse, mutect2, varscan2
- TEAD2 | c.883dup p.H295Pfs*19 | Frame Shift Ins (INS) | VAF 46/366 reads (13%) | catalogued as rs763321097; called by mutect2, varscan2
- TESK1 | c.1602G>A p.W534* | Nonsense Mutation (SNP) | VAF 17/40 reads (43%) | catalogued as COSV52410964; called by muse, mutect2, varscan2
- TLR6 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs375362297; called by muse, mutect2, varscan2
- TMEM132B | c.796C>G p.P266A | Missense Mutation (SNP) | VAF 130/236 reads (55%) | SIFT tolerated (0.19); PolyPhen benign (0.173); catalogued as rs747981993, COSV54752296; called by muse, mutect2, varscan2
- TSPYL5 | c.409dup p.R137Pfs*18 | Frame Shift Ins (INS) | VAF 4/30 reads (13%) | catalogued as rs775143186; called by mutect2, pindel
- UBN1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV52166506, COSV52167808; called by muse, mutect2, varscan2
- VPREB1 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs369071851; called by muse, mutect2, varscan2
- ZNF197 | c.3039C>G p.F1013L | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.063); catalogued as COSV56076406, COSV56076431; called by muse, mutect2, varscan2
- COL4A3 | c.4234G>A p.G1412S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM217B | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- FBXO34 | c.1844G>A p.R615K | Missense Mutation (SNP) | VAF 66/1016 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2
- HSPA2 | c.1369A>G p.N457D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.715); called by mutect2, varscan2
- KCNV2 | c.1552G>T p.V518L | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.043); called by muse, mutect2
- NRP2 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 42/844 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2
- OSMR | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 108/1730 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.196); called by muse, mutect2
- PARP2 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 48/551 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- PAXIP1 | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 38/728 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2
- RIOX1 | c.1556G>T p.R519M | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ROR2 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | called by mutect2, varscan2
- SLC49A3 | c.773dup p.M259Nfs*56 (on ENST00000404286 / NM_001294341.2; = p.M258Nfs*56 on NM_032219.4) | Frame Shift Ins (INS) | VAF 4/40 reads (10%) | called by pindel, varscan2
- SLC5A10 | c.851T>A p.I284N | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SMARCA2 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TCF7L2 | c.928C>T p.P310S (on ENST00000355995 / NM_001367943.1; = p.P287S on NM_030756.5) | Missense Mutation (SNP) | VAF 94/1120 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); called by muse, mutect2
- USP26 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ZMYM2 | c.1688C>T p.S563L | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2
- ZNF460 | c.1042A>G p.R348G | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- AOC3 | c.309G>A p.L103= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV53826247; called by muse, mutect2, varscan2
- C20orf194 | c.2940C>T p.G980= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- CA10 | c.654G>A p.Q218= | Silent (SNP) | VAF 96/1452 reads (7%) | called by muse, mutect2
- CLIP4 | c.1572C>G p.G524= | Silent (SNP) | VAF 91/219 reads (42%) | catalogued as COSV60748967; called by muse, mutect2, varscan2
- ELP3 | c.1311G>A p.L437= | Silent (SNP) | VAF 48/182 reads (26%) | catalogued as COSV56458898; called by muse, varscan2
- EOMES | c.909C>T p.N303= | Silent (SNP) | VAF 68/176 reads (39%) | catalogued as rs1247512523, COSV55412329; called by muse, mutect2, varscan2
- FER1L6 | c.891G>A p.K297= | Silent (SNP) | VAF 62/804 reads (8%) | called by muse, mutect2
- HTR3B | c.981C>G p.L327= | Silent (SNP) | VAF 161/406 reads (40%) | catalogued as COSV52744277, COSV99492197; called by muse, mutect2, varscan2
- JAG2 | c.264C>T p.C88= | Silent (SNP) | VAF 8/12 reads (67%) | called by muse, mutect2, varscan2
- LGALS13 | c.330C>T p.Y110= | Silent (SNP) | VAF 70/227 reads (31%) | catalogued as rs763680574, COSV55679864; called by muse, mutect2, varscan2
- LRP1 | c.129G>A p.K43= | Silent (SNP) | VAF 24/948 reads (3%) | catalogued as rs1290337300; called by muse, mutect2
- MPEG1 | c.1470C>T p.P490= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, varscan2
- MROH9 | c.1071C>T p.S357= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs760239861, COSV63011071; called by muse, mutect2, varscan2
- P2RY4 | c.330C>T p.F110= | Silent (SNP) | VAF 36/40 reads (90%) | catalogued as rs146718292, COSV65736416; called by muse, mutect2, varscan2
- SIPA1L3 | c.3498G>T p.S1166= | Silent (SNP) | VAF 40/125 reads (32%) | catalogued as COSV55913249; called by muse, mutect2, varscan2
- SLC12A3 | c.2592C>T p.F864= (on ENST00000563236 / NM_001126108.2; = p.F873= on NM_000339.3) | Silent (SNP) | VAF 78/210 reads (37%) | catalogued as rs771944220, COSV52632588; called by muse, mutect2, varscan2
- SLC26A4 | c.2208A>G p.Q736= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV55916340; called by muse, mutect2, varscan2
- TRH | c.168G>A p.R56= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as rs775338963, COSV57014898; called by muse, mutect2, varscan2
- UGT2B10 | c.1449C>G p.T483= | Silent (SNP) | VAF 359/995 reads (36%) | catalogued as COSV55322076; called by muse, mutect2, varscan2
- P4HTM | c.1074-11dup | Intron (INS) | VAF 12/64 reads (19%) | catalogued as rs760453324; called by mutect2, varscan2
